Gene-level copy-number profile of tumor specimen TCGA-AO-A124-01A from TCGA case TCGA-AO-A124, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 38.8 years (14,174 days).
Specimen TCGA-AO-A124-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.cea1bfb5-fe63-4515-8f2b-66696afa23b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A124-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/49ecf4a2-f266-44e9-a4d9-30e2853b2bc5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 4,628; copy number 2: 25,716; copy number 3: 14,967; copy number 4: 7,758; copy number 5: 4,017; copy number 6: 1,532; copy number 7: 429; copy number 8: 315; copy number 9: 251; copy number 10: 4; copy number 12: 20; copy number 14: 88; copy number 17: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A124-01A-11D-A10L-01): tumor purity 0.8, ploidy 2.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:159,128,802–159,128,894, 2 genes: MIR3688-1, MIR3688-2.
- chr11:134,945,118–135,075,908, 5 genes: AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr12:118,782,926–119,303,380, 14 genes (within-gene range 0–2): LINC02439, RNA5SP374, AC087863.2, AC087863.1, SRRM4, AC087885.1, RN7SL508P, AC084361.1, HSPB8, AC084880.4, AC084880.3, AC084880.1, AC084880.2, LINC00934.
- chr13:75,375,511–75,377,294, 1 gene: AL139230.1.
- chr14:66,507,407–67,181,803, 3 genes (within-gene range 0–2): GPHN, AL133241.1, AL049835.1.
- chr16:75,293,698–75,433,503, 3 genes (within-gene range 0–2): CFDP1, AC009054.1, AC009054.2.
- chr22:25,351,418–25,405,377, 1 gene: LRP5L.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,698 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:59,733,227–60,149,784, 8 genes, copy number 5: MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778.
- chr1:70,144,805–70,445,536, 10 genes, copy number 5: LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C, HHLA3, HHLA3-AS1, CTH, Metazoa_SRP, AL354872.1.
- chr1:163,769,339–164,899,296, 12 genes, copy number 5: AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA.
- chr1:176,857,302–178,038,007, 8 genes, copy number 5 (within-gene range 3–5): ASTN1, MIR488, BRINP2, LINC01645, AL136114.1, LINC01741, SEC16B, CRYZL2P-SEC16B.
- chr1:217,892,900–229,038,274, 274 genes, copy number 5–6 (broad region; genes not listed).
- chr1:229,812,917–248,919,946, 435 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:38,814–4,140,731, 71 genes, copy number 5 (broad region; genes not listed).
- chr2:38,193,348–39,128,927, 31 genes, copy number 6: AC009229.3, AC009229.1, RPL7P12, GAPDHP25, ATL2, LINC02613, AC016995.1, LINC01883, RPLP0P6, AC011247.2, HNRNPLL, AC011247.1, GALM, AC074366.1, SRSF7, GEMIN6, TTC39DP, NPLP1, DHX57, ASS1P2, AC018693.1, MORN2, RNU6-851P, ARHGEF33, RN7SL96P, AC019171.1, SOS1, SOS1-IT1, RNU6-198P, HSPE1P13, Y_RNA.
- chr2:59,647,621–67,825,562, 166 genes, copy number 5 (broad region; genes not listed).
- chr2:96,642,737–118,222,250, 436 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:158,419,955–159,904,756, 33 genes, copy number 5 (within-gene range 3–5): HNRNPDLP2, RN7SL393P, PKP4, RPL7AP22, PKP4-AS1, AC005042.1, AC005042.2, DAPL1, AC064843.1, OR7E89P, OR7E28P, OR7E90P, RNU2-21P, TANC1, BTF3L4P2, RNU6-580P, GSTM3P2, MIR6888, WDSUB1, BAZ2B, AC008277.1, AC008277.2, CAPZA1P2, Y_RNA, AC009506.1, AC009961.1, RPS3AP13, MARCHF7, CD302, LY75-CD302, AC009961.3, LY75, AC009961.2.
- chr3:88,317,156–91,513,775, 16 genes, copy number 5: ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr3:145,939,912–198,222,513, 930 genes, copy number 5–10 (broad region; genes not listed).
- chr5:170,747,047–172,283,764, 26 genes, copy number 6 (within-gene range 3–6): AC008514.1, GABRP, RANBP17, RN7SL623P, AC008514.2, USP12P1, AC091980.2, TLX3, AC091980.1, RN7SL339P, RPSAP71, SNORA70J, RPL10P8, MIR3912, NPM1, FGF18, AC093246.1, AC022440.1, AC011410.1, SMIM23, FBXW11, STK10, EFCAB9, UBTD2, AC024561.1, KLF3P1.
- chr6:7,232,556–36,639,672, 946 genes, copy number 5–9 (broad region; genes not listed).
- chr6:41,026,895–42,050,357, 46 genes, copy number 6 (within-gene range 4–6): UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2, FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P.
- chr6:53,561,289–53,924,125, 5 genes, copy number 6 (within-gene range 4–6): AL033397.1, LINC01564, KLHL31, AL590652.1, LRRC1.
- chr6:73,241,314–73,828,316, 24 genes, copy number 6 (within-gene range 4–6): KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109.
- chr6:79,201,245–155,455,839, 1,080 genes, copy number 5–17 (within-gene range 2–17) (broad region; genes not listed).
- chr6:168,194,358–168,319,777, 8 genes, copy number 5: AL611929.1, AL606970.5, AL606970.4, AL606970.2, AL606970.3, CTAGE13P, DACT2, AL606970.1.
- chr7:12,211,270–12,700,889, 13 genes, copy number 5: TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1.
- chr7:29,806,486–30,162,762, 12 genes, copy number 6 (within-gene range 4–6): WIPF3, AC004912.1, SCRN1, FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3.
- chr7:44,217,150–44,986,961, 25 genes, copy number 6: CAMK2B, AC004453.2, NUDCD3, AC004453.1, RNU6-1097P, AC004938.1, NPC1L1, DDX56, TMED4, AC004938.2, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1, AC004847.1, MYO1G, SNHG15, SNORA9.
- chr8:98,603,253–125,541,373, 375 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–3,526,004, 48 genes, copy number 8 (within-gene range 4–8): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1.
- chr9:34,957,608–35,758,585, 49 genes, copy number 5 (within-gene range 3–5): PHF24, DNAJB5-DT, DNAJB5, AL355377.1, AL355377.2, SYF2P2, AL355377.3, AL355377.4, AL353795.3, C9orf131, RN7SL338P, VCP, FANCG, PIGO, AL353795.2, STOML2, FAM214B, AL353795.1, UNC13B, AL160274.1, ATP8B5P, ZFAND6P1, RUSC2, AL133476.1, RPL36AP33, FAM166B, RPS29P17, AL357874.3, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2.
- chr10:44,712–5,945,900, 117 genes, copy number 5 (broad region; genes not listed).
- chr11:31,280,672–31,790,324, 6 genes, copy number 5 (within-gene range 2–5): CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1.
- chr11:33,665,220–36,697,867, 65 genes, copy number 5 (broad region; genes not listed).
- chr12:1,529,891–5,046,788, 99 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:9,817,350–12,267,044, 90 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr15:99,551,382–101,933,350, 70 genes, copy number 6 (broad region; genes not listed).
- chr16:11,555–25,021,023, 874 genes, copy number 5–9 (broad region; genes not listed).
- chr17:59,859,479–62,808,344, 91 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:706,523–832,469, 8 genes, copy number 7: AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1.
- chr18:13,824,149–14,252,140, 15 genes, copy number 8 (within-gene range 4–8): MC5R, MC2R, AP001086.1, AC006557.6, AC006557.5, ZNF519, AC006557.4, AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1.
- chr18:23,134,564–28,824,826, 90 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr18:35,904,818–36,187,448, 9 genes, copy number 5: MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1.
- chr18:49,946,266–50,988,121, 24 genes, copy number 7 (within-gene range 4–7): RNA5SP457, AC091044.1, ADAD1P2, AC105224.1, MIR4320, RN7SL310P, CFAP53, AC090246.1, MBD1, CXXC1, AC105227.1, AC105227.2, RNA5SP458, SKA1, RPLP0P11, MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1.
- chr20:56,468,585–57,458,298, 31 genes, copy number 5 (within-gene range 2–5): RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P, AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1.

Autosomal genes at a single copy (total copy number 1): 4,277. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
